HCMI case HCM-CSHL-0765-C56 — NCI Cancer Model Development for the Human Cancer Model Initiative (HCMI-CMDC)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Cystic, Mucinous and Serous Neoplasms; Primary site: Ovary. Index date (day 0 for every day count below): sample procurement.
https://portal.gdc.cancer.gov/cases/d2d0522a-bad8-4282-b67d-bed52e7efab4

Demographics
Sex at birth: female; Days to birth: -27,375 days (74.9 years before the index date); Year of birth: 1944.

Diagnoses (2)
1. Serous surface papillary carcinoma (the primary disease): ICD-O-3 morphology code: 8461/3; ICD-10 code: C56; Tissue or organ of origin: Ovary; Classification of tumor: primary; Metastasis at diagnosis: Metastasis, NOS; Prior treatment: No; Sites of involvement: Omentum / Diaphragm / Bladder, NOS / Spleen / Ovary, NOS.
   Recorded as not given: neoadjuvant treatment (type not reported).
2. Serous surface papillary carcinoma: ICD-O-3 morphology code: 8461/6; ICD-10 code: C78.6; Tissue or organ of origin: Ovary; Site of resection or biopsy: Specified parts of peritoneum; Classification of tumor: metastasis; Sites of involvement: Diaphragm / Bladder, NOS / Spleen.

Follow-up (5 entries)
- Days to follow up: 0 days; Progression or recurrence: Yes; Progression or recurrence anatomic site: Specified parts of peritoneum; Days to progression: 0 days.
- Days to follow up: 0 days; Progression or recurrence: Yes; Progression or recurrence anatomic site: Spleen; Days to progression: 0 days.
- Days to follow up: 0 days; Progression or recurrence: Yes; Progression or recurrence anatomic site: Connective, subcutaneous and other soft tissues of thorax; Days to progression: 0 days.
- Days to follow up: 0 days; Progression or recurrence: Yes; Progression or recurrence anatomic site: Bladder, NOS; Days to progression: 0 days.
- Follow-up contact recording only the day: day 143.

Other clinical attributes
- Timepoint category: Initial Diagnosis; Weight: 50.5 kg; Height: 166 cm; BMI: 18.3.

Family history
- Relationship type: First Degree Relative, NOS.

Biospecimens (2 samples)
- Sample HCM-CSHL-0765-C56-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Whole Blood; Preservation method: Frozen.
- Sample HCM-CSHL-0765-C56-85P: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Metastatic; Specimen type: 3D Organoid; Preservation method: Frozen; Passage count: 6.
